Somatic mutation profile of tumor specimen MBCProject_5856_T0C_WES (aliquot MBCProject_5856_T0C_WES_1) from CMI case MBCProject_5856, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 60.0 years (21,902 days).
Specimen MBCProject_5856_T0C_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Axilla; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c97351e8-890f-407f-847f-a6c1e889504e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_5856_SALIVA (Saliva), aliquot MBCProject_5856_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ad0d103-f4b4-460c-abb5-d43f97ee6e58

The open-access MAF lists 132 somatic variants for this specimen: 89 protein-altering or splice-affecting, 28 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 28, Intron 6, Nonsense Mutation 6, 5'UTR 3, RNA 3, Splice Region 2, Frame Shift Del 2, 3'Flank 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM5 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776309636, COSV59375732; called by muse, mutect2, varscan2
- ATP2B2 | c.3298G>A p.E1100K (on ENST00000352432; = p.E1066K on NM_001683.5) | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.265); catalogued as rs772535893; called by muse, mutect2, varscan2
- BRWD3 | c.4747G>A p.E1583K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.899); catalogued as rs761994597; called by muse, mutect2
- CCDC178 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV55791877; called by muse, varscan2
- CPO | c.810G>C p.L270F | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55939045; called by muse, mutect2, varscan2
- DPM3 | c.225G>C p.Q75H (on ENST00000341298; = p.Q105H on NM_018973.3) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as COSV57597502; called by muse, mutect2, varscan2
- DST | c.16468G>A p.E5490K (on ENST00000361203 / NM_001374722.1; = p.E3078K on NM_015548.5) | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.268); catalogued as COSV55025988; called by muse, mutect2, varscan2
- ESPNL | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs1447506808; called by muse, mutect2, varscan2
- FERMT1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1399325233; called by muse, varscan2
- GALNT10 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.269); catalogued as rs377183023; called by muse, mutect2, varscan2
- GLA | c.961C>A p.Q321K | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as CM051535, CM993663; called by muse, mutect2, varscan2
- HERC1 | c.4045G>A p.E1349K | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.971); catalogued as rs1198822222; called by muse, mutect2, varscan2
- MX1 | c.1328G>C p.R443T | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55818793; called by muse, varscan2
- NRSN1 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs751622322; called by mutect2, varscan2
- OR4A15 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as rs1410474772; called by muse, mutect2, varscan2
- OR5AR1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV57253529; called by muse, mutect2, varscan2
- PDE4D | c.1372G>A p.D458N (on ENST00000340635 / NM_001104631.2; = p.D322N on NM_006203.4) | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.952); catalogued as COSV57721659; called by muse, mutect2, varscan2
- PHYHD1 | c.417G>C p.Q139H | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as rs1206830767; called by muse, mutect2, varscan2
- PIGO | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV53054428, COSV53055670; called by muse, mutect2, varscan2
- RBM12 | c.1080G>C p.L360F | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58290599; called by muse, mutect2
- RNPEPL1 | c.1387G>C p.D463H | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54374187; called by muse, mutect2, varscan2
- SPRTN | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763031758, COSV50478047; called by muse, mutect2, varscan2
- TBRG4 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.218); catalogued as rs1214359295; called by muse, mutect2, varscan2
- TMC3 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs201479309; called by muse, mutect2, varscan2
- TTC21B | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768266139, COSV99692928; called by muse, mutect2, varscan2
- WASHC2C | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV60493560; called by muse, mutect2, varscan2
- ZNF385A | c.245G>A p.R82H (on ENST00000338010 / NM_001130967.3; = p.R62H on NM_015481.3) | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757518593; called by muse, mutect2, varscan2
- ZNF420 | c.1904G>T p.R635I | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as rs985693507, COSV100421324; called by muse, mutect2, varscan2
- ZNF804A | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV56450536; called by muse, mutect2, varscan2
- ABCA12 | c.5389C>T p.H1797Y (on ENST00000272895 / NM_173076.3; = p.H1479Y on NM_015657.3) | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, varscan2
- ALDH5A1 | c.1300T>C p.C434R | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, varscan2
- AMER1 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- ANKRD28 | c.1636G>C p.D546H | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- ATP2A1 | c.2978A>C p.E993A | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- C5orf49 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); called by muse, varscan2
- CDH1 | c.801del p.F267Lfs*15 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- CPEB1 | c.1006G>C p.E336Q (on ENST00000617958; = p.E276Q on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CRYBG2 | c.2617C>A p.L873M | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.866); called by mutect2, varscan2
- DDX4 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- DEPDC5 | c.3193C>T p.Q1065* (on ENST00000400246; = p.Q1134* on NM_014662.5) | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2, varscan2
- EHF | c.140del p.P47Lfs*42 | Frame Shift Del (DEL) | VAF 43/162 reads (27%) | called by mutect2, pindel, varscan2
- FXR1 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- FZD2 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GFY | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); called by muse, mutect2
- GNGT1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0.148); called by muse, varscan2
- HMCN1 | c.3097G>A p.D1033N | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGFBP4 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); called by muse, mutect2
- KCNK2 | c.944C>T p.S315F (on ENST00000444842 / NM_001017425.3; = p.S300F on NM_014217.4) | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- KIF13A | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- KLHL7 | c.970G>A p.E324K (on ENST00000339077 / NM_001031710.3; = p.E276K on NM_018846.5) | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- KRTAP16-1 | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- LRRC8E | c.1967A>T p.E656V | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- LUC7L3 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MAP2 | c.2701G>T p.D901Y | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- MAP2 | c.2782G>A p.E928K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.519); called by muse, varscan2
- MARCHF7 | c.1874G>C p.R625T | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- METTL21A | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- MFAP3L | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.053); called by mutect2, varscan2
- MIER3 | c.1028G>C p.R343T (on ENST00000381199 / NM_001297599.2; = p.R342T on NM_152622.4) | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- MIIP | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MINAR1 | c.1463G>A p.R488K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- MRPS9 | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- MTUS2 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- PCYOX1 | c.114G>A p.A38= | Splice Region (SNP) | VAF 18/96 reads (19%) | called by muse, mutect2, varscan2
- PHYHD1 | c.457+3G>C | Splice Region (SNP) | VAF 20/151 reads (13%) | called by muse, mutect2, varscan2
- PI4KA | c.412C>G p.L138V | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.079); called by muse, varscan2
- PRC1 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRKX | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); called by muse, varscan2
- PTPRJ | c.2686C>T p.Q896* | Nonsense Mutation (SNP) | VAF 50/227 reads (22%) | called by muse, mutect2, varscan2
- PTPRQ | c.4803G>A p.W1601* (on ENST00000616559; = p.W1559* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- RIOK3 | c.1176G>T p.L392F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- RNF217 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | called by mutect2, varscan2
- RTCA | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.05); called by muse, varscan2
- SASH3 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- SEC14L6 | c.1185G>C p.E395D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SGCD | c.481G>A p.E161K (on ENST00000435422 / NM_001128209.2; = p.E162K on NM_000337.5) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.242); called by muse, varscan2
- SNX13 | c.2020G>C p.E674Q | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- SRFBP1 | c.1223G>A p.R408K | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.103); called by muse, varscan2
- STAB2 | c.6320C>G p.S2107C | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TAS1R3 | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBCK | c.1549G>A p.E517K (on ENST00000273980 / NM_001163436.4; = p.E454K on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, varscan2
- TRIOBP | c.2687C>G p.S896C | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRMT2B | c.1312C>G p.R438G | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- WASHC5 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 48/302 reads (16%) | called by muse, varscan2
- WDR24 | c.12G>C p.K4N | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- WDR36 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- WDR75 | c.856C>T p.L286F | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF420 | c.1610G>C p.G537A | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF853 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 16/185 reads (9%) | called by muse, mutect2
- ADCYAP1R1 | c.984C>A p.I328= | Silent (SNP) | VAF 17/147 reads (12%) | called by muse, mutect2, varscan2
- ARAP1 | c.123C>G p.L41= | Silent (SNP) | VAF 14/64 reads (22%) | called by muse, varscan2
- ATP10A | c.4101C>T p.S1367= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs139061181; called by muse, mutect2
- ATP11B | c.2965C>T p.L989= | Silent (SNP) | VAF 25/168 reads (15%) | called by mutect2, varscan2
- C3 | c.1908C>T p.A636= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as rs757684194, COSV55571534; called by muse, mutect2, varscan2
- CEP290 | c.5574C>G p.T1858= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV58348647; called by muse, mutect2
- CYB561A3 | c.132C>T p.F44= | Silent (SNP) | VAF 18/80 reads (23%) | called by muse, mutect2, varscan2
- GBP6 | c.277C>T p.L93= | Silent (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- GSG1L | c.744C>T p.F248= (on ENST00000447459 / NM_001109763.2; = p.F93= on NM_144675.2) | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as rs1374424879; called by muse, mutect2, varscan2
- ICE1 | c.1629C>T p.L543= | Silent (SNP) | VAF 28/120 reads (23%) | called by muse, mutect2, varscan2
- INO80 | c.2280G>A p.E760= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV62740781, COSV62741023; called by muse, varscan2
- JAKMIP2 | c.342C>G p.L114= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV54615874; called by muse, mutect2, varscan2
- KAT6B | c.141C>G p.V47= | Silent (SNP) | VAF 38/205 reads (19%) | called by muse, mutect2, varscan2
- KCTD3 | c.918C>T p.V306= | Silent (SNP) | VAF 38/231 reads (16%) | catalogued as rs752572246; called by muse, mutect2, varscan2
- KMO | c.591G>A p.L197= | Silent (SNP) | VAF 17/94 reads (18%) | called by muse, varscan2
- MECP2 | c.1008G>A p.L336= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV57656299; called by muse, varscan2
- MXRA5 | c.7164C>T p.I2388= | Silent (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- MYO1B | c.2349C>G p.V783= | Silent (SNP) | VAF 67/274 reads (24%) | catalogued as rs768492272; called by muse, mutect2, varscan2
- OR4S1 | c.585C>T p.L195= | Silent (SNP) | VAF 23/99 reads (23%) | called by muse, mutect2, varscan2
- PPOX | c.564C>T p.F188= | Silent (SNP) | VAF 39/317 reads (12%) | called by muse, mutect2, varscan2
- SERPINB8 | c.928C>T p.L310= | Silent (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- SLC19A3 | c.732G>C p.L244= | Silent (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- SYNE1 | c.15933G>C p.V5311= (on ENST00000367255 / NM_182961.4; = p.V5240= on NM_033071.3) | Silent (SNP) | VAF 21/110 reads (19%) | called by muse, mutect2, varscan2
- TMCC2 | c.1839G>A p.L613= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- TTN | c.60594G>A p.A20198= (on ENST00000591111; = p.A12774= on NM_003319.4) | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs1390911668, COSV100618087, COSV60172024; ClinVar: likely benign; called by muse, varscan2
- VGLL2 | c.642C>T p.L214= | Silent (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- WDR91 | c.2190C>T p.T730= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs145873188; called by muse, mutect2, varscan2
- XIRP1 | c.171C>T p.L57= | Silent (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- AC078880.2 | n.234C>T | RNA (SNP) | VAF 29/143 reads (20%) | called by muse, mutect2, varscan2
- ACTG1 | c.*118G>C | 3'UTR (SNP) | VAF 51/265 reads (19%) | catalogued as rs782523909; called by muse, mutect2, varscan2
- ATG12 | c.163+51G>A | Intron (SNP) | VAF 50/295 reads (17%) | called by muse, mutect2, varscan2
- CLK2P1 | n.674G>A | RNA (SNP) | VAF 17/234 reads (7%) | called by muse, mutect2
- COG6 | c.153+284G>A | Intron (SNP) | VAF 37/148 reads (25%) | called by muse, mutect2, varscan2
- ESPN | chr1:6457184 G>A | 3'Flank (SNP) | VAF 19/88 reads (22%) | catalogued as rs549758416; called by muse, mutect2, varscan2
- HEXIM2 | c.-215G>A | 5'UTR (SNP) | VAF 22/335 reads (7%) | catalogued as rs1336736425; called by muse, mutect2
- HOXB3 | c.-159+712G>A | Intron (SNP) | VAF 16/82 reads (20%) | called by muse, varscan2
- NASP | c.2158-17C>T | Intron (SNP) | VAF 25/107 reads (23%) | called by muse, mutect2, varscan2
- PDXDC1 | chr16:14974730 A>T | 5'Flank (SNP) | VAF 18/138 reads (13%) | called by muse, varscan2
- PPFIA4 | c.-194C>T | 5'UTR (SNP) | VAF 15/84 reads (18%) | catalogued as rs746704775; called by muse, varscan2
- SLC29A1 | c.-167C>G | 5'UTR (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- TMEM183B | n.144G>A | RNA (SNP) | VAF 18/97 reads (19%) | catalogued as rs757751312; called by muse, mutect2, varscan2
- TRIP12 | c.2353-39C>T | Intron (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- TTC21B | c.1386+75G>C | Intron (SNP) | VAF 14/75 reads (19%) | called by muse, mutect2, varscan2
